Somatic mutation profile of tumor specimen 0DUFEC from CCDI case PBCLCD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,137 days).
Specimen 0DUFEC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1a62818-1f74-40ad-be25-d696f5f9e70d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUFDD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/161e6fdf-424a-4587-a457-5974d1bb9f8c

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 194/388 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDH12 | c.2312G>T p.W771L | Missense Mutation (SNP) | VAF 141/357 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs1178639815; called by muse, mutect2, varscan2
- FAM71A | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 125/262 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs201312997, COSV54237337; called by muse, mutect2, varscan2
- LTV1 | c.759T>A p.N253K | Missense Mutation (SNP) | VAF 122/292 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100849611; called by mutect2, varscan2
- RBFOX1 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 39/538 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.656); catalogued as rs781081302, COSV60947493; called by muse, mutect2
- LYSMD2 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 156/353 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NEFM | c.2101C>A p.Q701K | Missense Mutation (SNP) | VAF 255/618 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ABCD1 | c.2202G>T p.P734= | Silent (SNP) | VAF 132/311 reads (42%) | called by muse, mutect2, varscan2
- ANKRD23 | c.273C>T p.P91= | Silent (SNP) | VAF 226/491 reads (46%) | catalogued as rs1349951090; called by muse, mutect2, varscan2
- RAD21 | c.1471-80A>G | Intron (SNP) | VAF 32/49 reads (65%) | called by muse, mutect2, varscan2
- TMEM138 | c.-21del | 5'UTR (DEL) | VAF 52/144 reads (36%) | called by mutect2, pindel, varscan2
